Surgical pathology report (de-identified scan), TCGA case TCGA-18-3417, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Princess Margaret Hospital (Canada), specimen TCGA-18-3417-01A (Primary Tumor).

[page 1 of 10]
Surgical Pathology Consultation Report

* Addended *

SPECIMEN(S) RECEIVED

1. Lymph-Node: ST9 Inf Pulm Ligament
2. Lymph node: ST12R Lobar right
3. Lymph node: RT TB angle ST10R
4. Lymph node: ST12R lobar right
5. Lymph node: interlobar ST11
6. Lymph node: interlobar ST11; posterior right
7. Lymph node: subcarinal ST7
8. LUNG: right lung bronchial resection with ribs 4 & 5

DIAGNOSIS

1-3. Lymph nodes, biopsies (ST9 inferior pulmonary ligament, ST12R right lobar, ST10R right TB angle):

- Lymph nodes, negative for malignancy (x3)

4. "Lymph node", biopsy (ST12R right lobar):

- Fibroadipose and granulation tissue with cautery and crush artefact, negative for malignancy
- No lymph node identified

5. Lymph node, biopsy (ST11 interlobar):

- Positive for poorly differentiated squamous carcinoma
- No lymph node identified

6. "Lymph node", (ST11 interlobar; posterior right):

- Soft tissue with poorly differentiated squamous carcinoma (see Comment)
- No lymph node identified

7. Lymph node, (subcarinal ST7):

- Lymph node, negative for malignancy

[page 2 of 10]
8. Lung, right pneumonectomy and partial chest wall resection:
- a) Poorly differentiated squamous carcinoma (see Comment) with:
- i) Involvement of right upper and lower lobes.
- ii) Greatest dimension in right lower lobe = 5.0 cm
- iii) Greatest dimension in right upper lobe = 3.0 cm
- iv) Visceral pleural invasion present.
- v) Vascular invasion present.
- vi) Bronchial resection margin negative for malignancy.
- vii) Six of thirty-one peribronchial lymph nodes positive for carcinoma (6/31)
- viii) Pathological Stage: pT2N1M1
- b) Lung with:
- i) Multifocal infarcts
- ii) Patchy chronic inflammation and focal interstitial fibrosis of uncertain significance

SYNOPTIC DATA

Specimen Type:	Pneumonectomy
Laterality:	Right
Tumor Site:	Other: (Right upper and lower lobes)
Tumor Size:	Greatest dimension: 5.0 cm
Histologic Type:	Squamous cell carcinoma
Histologic Grade:	G3: Poorly differentiated
Pathologic Staging (pTNM):	pT2: Tumor with any of the following features of size or extent: greater than 3 cm in greatest dimension; involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region but does not involve the entire lung
	pN1: Metastasis in ipsilateral peribronchial and/or ipsilateral hilar lymph nodes, including intrapulmonary nodes involved by direct extension of the primary tumor
	Lymph node stations involved: 10R (Right hilar), 11R (Right interlobar)
	pM1: Distant metastasis; includes separate tumor nodule(s) in a different lobe (ipsilateral or contralateral)
Margins:	Margins uninvolved by invasive carcinoma
	Distance of invasive carcinoma from

[page 3 of 10]
closest margin: 15 mm

Direct Extension of Tumor:	Margin: (Bronchial)
Blood Vessel Invasion:	Visceral pleura
Lymphatic (Small Vessel) Invasion (L):	Present
Additional Pathologic Findings:	Inflammation (type): Patchy chronic interstitial inflammation
	Other: Focal pulmonary infarcts

COMMENT

6. Sections of specimen 6 show soft tissue with rare small clusters of tumour cells. One such cluster demonstrates probable perineural invasion.

8. Sections show two separate tumors composed of poorly differentiated carcinoma with focal suggestion of squamous differentiation. The larger tumor is found superiorly in the lower lobe. This tumor invades and puckers the overlying pleura, but chest wall invasion and invasion into the upper lobe are not identified. However, a second tumor is identified more centrally in the upper lobe. This is separate from the RLL tumor, measures 3 cm in greatest dimension, and shows similar histology to that of the RLL tumor. The tumor demonstrates extensive vascular invasion, including invasion of some larger vessels, and several pulmonary infarcts are noted in the upper lobe. Multiple peribronchial lymph nodes are involved by tumor, including by direct invasion of the RUL tumor. By immunohistochemistry, the tumor cells show strong cytoplasmic staining for 5/6, focal moderate staining for high and low molecular weight cytokeratin, and moderate to strong nuclear staining for p63. The tumor cells are negative for cytokeratin 7 and 20, and TTF-1. The morphological and immunohistochemical features are consistent with poorly differentiated squamous cell carcinoma. Given the morphologic similarities between the RUL and RLL tumors and the extent of vascular invasion, the RUL tumor is strongly favored to represent a metastasis from the RLL tumor. The pathologic stage is therefore assessed to be pT2N1M1.

[page 4 of 10]
CLINICAL HISTORY
LUNG CA

GROSS DESCRIPTION

1. The specimen labeled with the patient's name and as "Lymph-Node: ST9 Inf Pulm Ligament" consists of two black, firm lymph nodes covered by a few fragments of adipose tissue; received in 10% buffered formalin. They measure 0.6 x 0.4 x 0.4 cm and 0.7 x 0.4 x 0.3 cm.

1A specimen is submitted in toto

The specimen is labeled with the patient's name and as "Lymph node: '12R Lobar right/QS". It consists of multiple fragments of dark brown-black tissue measuring 0.5 x 0.5 x 0.3 cm in aggregate. The specimen is submitted in toto for frozen section.

2A frozen section control

3. The specimen labeled with the patient's name and as "Lymph node: RT TB angle ST10R/QS". Consists of five tan-black lymph nodes, the largest measuring 0.9 x 0.8 x 0.3 cm; received fresh. The specimen is submitted in total for frozen section.

3A-3B frozen section control

4. The specimen is labeled with the patient's name and as "Lymph node: ST12R lobar right/QS". It consists of two fragments of tan-black tissue, the largest measuring 0.8 x 0.6 x 0.2 cm. The specimen is submitted in toto for frozen section.

4A frozen section control

5. The specimen is labeled with the patient's name and as "Lymph node: interlobar ST11/QS". It consists of two fragments of tan-black tissue, the largest measuring 0.3 x 0.4 x 0.3 cm. The specimen is submitted in toto for frozen section.

5A frozen section control

6. The specimen is labeled with the patient's name and as "Lymph node: interlobar ST11; posterior right/QS". It consists of two fragments of tan-black tissue measuring 0.5 x 0.6 x 0.3 cm. The specimen is submitted in toto for frozen section.

frozen section control

[page 5 of 10]
7. The specimen is labeled with the patient's name and as "Lymph node: subcarinal ST 7/QS". It consists of a fragment of tan-red tissue measuring 3.0 x 2.5 x 1.0 cm. The specimen is submitted in toto for frozen section.

7A-7C frozen section control

7D remaining fragments, EIT

8. The specimen labeled with the patient's name and as "LUNG: right lung bronchial resection with ribs 4 & 5/QS". The specimen is received fresh and subsequently placed in to 10% buffered formalin. It consists of a right lung: upper, middle and lower lobes, with overall dimensions of 21.0 cm SI x 21.0 cm ML x 7.5 cm AP. A small portion of unremarkable 4th and 5th ribs are identified on the upper lobe, measuring 5.0 x 1.4 x 0.7 cm and 7.4 x 1.4 x 0.8 cm. The pleural surfaces of all three lobes are homogeneously purple and congested, showing diffuse black pigmentation.

Cross sections of the right upper lobe reveal three separate, poorly defined lesions. The largest measuring 3.0 x 3.0 x 2.3 cm, located within the anterior segment. The cut surface of this lesion is homogeneously white and firm. Further sections show gross invasion into the bronchus and adjacent lymph nodes. This tumor is located 1.5 cm from the bronchial resection margin, and 0.6 cm from the closest pleural surface. The two smaller lesions are located 2.0 cm beneath the ribs, within the anterior aspect. Both lesions are homogeneously tan, solid and grossly appear to have a red hemorrhagic center measuring 1.2 x 0.7 x 0.7 cm and 1.5 x 1.0 x 1.0 cm. The distance between the two smaller lesions is 0.6 cm. Both lesions are located 5.0 cm from the bronchial resection margin and 1.1 cm from the closest pleural surface. The remaining parenchyma of the right upper lobe is homogeneously dark brown and unremarkable.

Cross sections of the right middle lobe are homogeneously dark brown, spongy and unremarkable.

Within the superior segment of the right lower lobe, a well-circumscribed tumor is noted measuring 5.0 x 4.0 x 4.4 cm. The cut surface of the tumor is homogeneously white and firm; located 5.5 cm from the bronchial resection margin. Cross sections of the tumor show that it abuts the pleural surface, causing "pleural puckering". Further sections reveal gross invasion into the pleura. Approximately 1.5 cm from the larger tumor, a smaller calcified nodule is noted (within the base of the right lower lobe) measuring 0.4 x 0.3 x 0.2 cm. The remaining parenchyma of

[page 6 of 10]
the right lower lobe is homogeneously dark brown and otherwise unremarkable.

Multiple lymph nodes are noted throughout the right lung, ranging from 0.3 to 2.8 cm. Four pieces of tumor and four pieces of normal lung parenchyma have been taken for tissue banking. The bronchial resection margin has been removed (en face) and submitted for intraoperative consultation by frozen section.

Representative sections are submitted as follows:

8A	bronchial resection margin, frozen section block resubmitted
8B-8C	smallest tumor in RUL, EIT
8D-8E	mid sized tumor in RUL, EIT
8F	section containing both smallest and mid sized tumor, RUL
8G	representative section of largest tumor RUL, showing invasion into bronchus
8H	representative section of largest tumor RUL, showing invasion into adjacent lymph nodes
8I-8J	representative sections of largest tumor, RUL
8K-8L	representative sections of normal lung parenchyma, RUL
8M-8O	representative sections of RML
8P-8Q	representative sections of larger tumor within RLL with adjacent pleura (showing invasion)
8R-8T	representative sections of larger tumor within RLL
8U	calcified nodule within base of RLL, EIT
8V-8W	representative sections of largest lobar lymph node, RUL
8X	one segmental lymph node, RUL
8Y-8AB	one bisected segmental lymph node per block, RUL
8AC-8AD	one trisected segmental lymph node per block, RUL
8AE	one fragmented segmental lymph node, RUL
8AF	two subsegmental lymph nodes, RUL
8AG	one subsegmental lymph node, RUL
8AH-8AK	one bisected subsegmental lymph node per block, RUL
8AL-8AM	one bisected lobar lymph node per block, RLL
8AN	one trisected lobar lymph node, RLL
8AO-8AP	one bisected segmental lymph node per block, RLL
8AQ-8AR	one trisected segmental lymph node per block, RLL
8AS	four subsegmental lymph nodes, RLL
8AT	three subsegmental lymph nodes, RLL
8AU	one subsegmental lymph node, RLL
8AV-8AX	one bisected subsegmental lymph node per block, RLL

[page 7 of 10]
[REDACTED]

QUICK SECTION

2A, 3A-3B, 7A-7C, 8A = negative for malignancy

4A - atypical cell present, can't rule out malignancy

5A - mets carcinoma, large cell type

6A - atypical cells present, consistent with malignancy

[REDACTED]

Addendum Comment

The case was reviewed by [REDACTED]
Services. A copy of [REDACTED] has been scanned into
Co-path which is as follows:

[REDACTED]

[REDACTED]

ADMITTING DR.: PHYSICIAN NOT ON FILE
ORDERING DR. : PHYSICIAN NOT ON FILE

[REDACTED]

CLINICAL DATA AND MATERIAL SUBMITTED :

[REDACTED]

[page 8 of 10]
[REDACTED]

Consult received from [REDACTED]

A. [REDACTED], 64 stained slides and report dated [REDACTED]
All original stained slides will be returned along with a copy of this report.

FINAL DIAGNOSIS

RIGHT LUNG, PNEUMONECTOMY WITH CHEST WALL RESECTION

: SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED

: VISCERAL PLEURA INVOLVED BY TUMOUR

: BRONCHIAL MARGIN CLEAR

METASTATIC SQUAMOUS CELL CARCINOMA IN RIGHT UPPER LOBE, SEE COMMENT

MULTIPLE INFARCTS, UPPER LOBE

LYMPH NODES, PERIBRONCHIAL

: METASTATIC SQUAMOUSCELL CARCINOMA (6 OF 31)

LYMPH NODE, STATION 11 INTERLOBAR, BIOPSIES

: METASTATIC SQUAMOUSCELL CARCINOMA

LYMPH NODE, STATION 12 RIGHT LOBAR, BIOPSY

: FIBROUS SCARRING, NEGATIVE FOR MALIGNANCY

LYMPH NODES, STATION 9 INFERIOR PULMONARY LIGAMENT AND STATION 7

SUBCARINAL, BIOPSIES

: NEGATIVE FOR MALIGNANCY

LYMPH NODES, STATION 12 RIGHT LOBAR, STATION 10 RIGHT TB ANGLE, BIOPSIES

: NEGATIVE FOR MALIGNANCY

[REDACTED]

(Cont 'd)

[REDACTED]

[page 9 of 10]
SURGICAL PATHOLOGY CONSULTATION REPORT

ADMITTING DR.: PHYSICIAN NOT ON FILE
NOPTIC REPORT FOR LUNG CANCER RESECTION

SPECIMEN TYPE: Right pneumonectomy.

HISTOLOGIC TYPE : Squamous cell carcinoma.

HISTOLOGIC GRADE: Poorly differentiated.

PRIMARY TUMOUR SIZE: 5.0 cm x 4.0 cm x 4.4 cm

PRIMARY TUMOUR SITE: Right lower lobe.

ADDITIONAL TUMOUR NODULES: Right upper lobe nodule measuring 3.0 x 3.0 x 2.3 cm.

EXTENT OF TUMOUR

VISCERAL PLEURA: Involved by tumour.
PARIETAL PLEURA: Not involved.
CHEST WALL: Not involved.
LYMPHATIC INVASION: Present.
VASCULAR INVASION: Present.
OTHER STRUCTURES: Not applicable.

MARGINS OF EXCISION

BRONCHIAL MARGIN: Clear of tumour.
MEDIASTINAL MARGIN: Clear of tumour.
OTHER MARGINS: Not applicable.

MPH NODES

N1: 6 of 31 peribronchial nodes negative malignancy.

[page 10 of 10]
[REDACTED]

N2: 2 of 2 nodes negative for malignancy inferior pulmonary ligament node and subcarinal node) .

COMMENT: The pneumonectomy contains two tumour nodules, the dominant residing in the right lower lobe is considered the primary and the smaller upper lobe nodule is considered a hematogenous metastasis. The smaller nodules in the right upper lobe are seen to be organizing infarcts.

[REDACTED]

(Cont. 1d)

[REDACTED]

PAGE 13

[REDACTED]

SURGICAL PATHOLOGY CONSULTATION REPORT
LOCATION : CONS.

[REDACTED]

RESULTS VERIFIED - SIGNATURE ON FILE

[REDACTED]

END OF REPORT

Source: NCI Genomic Data Commons file 35fe53dc-a29f-4a6e-bc3d-3ad0d55b81f7 (TCGA-18-3417.71B38C75-44CF-4F27-90C2-04CAEE0D55A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).